Somatic mutation profile of tumor specimen ALCH-B48S-TTP1-A (aliquot ALCH-B48S-TTP1-A-6-0-D-A799-36) from ALCHEMIST case ALCH-B48S, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: male; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 60.9 years (22,238 days).
Specimen ALCH-B48S-TTP1-A: Sample type: FFPE Scrolls; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 64c388b1-c3b2-4e6e-b2aa-c26628fc5fc3.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-B48S-NB1-A (Blood Derived Normal), aliquot ALCH-B48S-NB1-A-1-0-D-A799-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/e36f2544-adf9-4cad-91c1-a34f20ca2c54

The open-access MAF lists 167 somatic variants for this specimen: 107 protein-altering or splice-affecting, 34 silent, 26 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 91, Silent 34, 5'UTR 9, Intron 7, Nonsense Mutation 6, RNA 5, In Frame Del 3, 3'UTR 3, Splice Site 3, Frame Shift Del 2, Splice Region 2, 5'Flank 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- EGFR | c.2240_2257del p.L747_P753delinsS | In Frame Del (DEL) | VAF 59/278 reads (21%) | hotspot (GDC flag); catalogued as rs121913438, COSV51767961; ClinVar: drug response; called by pindel, varscan2
- TP53 | c.673-2A>G p.X225_splice | Splice Site (SNP) | VAF 127/216 reads (59%) | hotspot (GDC flag); catalogued as rs1555525585, CS109519, COSV52669186, COSV52682653, COSV52687702; ClinVar: likely pathogenic / pathogenic / not provided; called by muse, mutect2, varscan2
- ARPC5L | c.163C>T p.R55W | Missense Mutation (SNP) | VAF 40/202 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.892); catalogued as rs1417524107; called by muse, mutect2, varscan2
- C20orf144 | c.319C>A p.P107T | Missense Mutation (SNP) | VAF 9/91 reads (10%) | SIFT tolerated (0.47); PolyPhen benign (0.05); catalogued as COSV55778649; called by muse, mutect2
- CIC | c.1453G>A p.E485K | Missense Mutation (SNP) | VAF 27/95 reads (28%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.054); catalogued as COSV50556433, COSV50560972; called by muse, mutect2, varscan2
- CRLF1 | c.1054G>A p.E352K | Missense Mutation (SNP) | VAF 17/21 reads (81%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.114); catalogued as COSV62260934; called by muse, mutect2
- CTSC | c.725G>T p.G242V | Missense Mutation (SNP) | VAF 42/196 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as CD013843; called by muse, mutect2, varscan2
- EXOSC1 | c.312-1G>C p.X104_splice | Splice Site (SNP) | VAF 35/79 reads (44%) | catalogued as rs937077735; called by muse, mutect2, varscan2
- EYS | c.6302C>G p.S2101C | Missense Mutation (SNP) | VAF 16/205 reads (8%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.819); catalogued as COSV65481975; called by muse, mutect2
- EZHIP | c.1235C>T p.S412L | Missense Mutation (SNP) | VAF 8/54 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs898488811; called by muse, mutect2, varscan2
- FLYWCH1 | c.289G>C p.E97Q | Missense Mutation (SNP) | VAF 4/38 reads (11%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs772778422, COSV54146245; called by mutect2, varscan2
- FUT4 | c.604G>C p.D202H | Missense Mutation (SNP) | VAF 11/104 reads (11%) | SIFT tolerated (0.55); PolyPhen benign (0.001); catalogued as rs984644159, COSV62469209, COSV62469259, COSV62470017; called by muse, mutect2
- GLB1L2 | c.436G>A p.G146R | Missense Mutation (SNP) | VAF 15/83 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs754533553, COSV100335526; called by muse, mutect2, varscan2
- GRAMD2B | c.286G>C p.E96Q | Missense Mutation (SNP) | VAF 9/197 reads (5%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.503); catalogued as COSV53506678, COSV53507260; called by muse, mutect2
- GUCA1B | c.355G>C p.E119Q | Missense Mutation (SNP) | VAF 20/301 reads (7%) | SIFT tolerated (0.27); PolyPhen benign (0.029); catalogued as COSV57834836; called by muse, mutect2
- HIVEP2 | c.4640C>T p.S1547F | Missense Mutation (SNP) | VAF 13/128 reads (10%) | SIFT tolerated (0.74); PolyPhen benign (0); catalogued as rs767483585; called by muse, mutect2, varscan2
- HPN | c.1103G>A p.R368H | Missense Mutation (SNP) | VAF 46/187 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1324597452, COSV52882030; called by muse, mutect2, varscan2
- L3MBTL1 | c.248C>T p.S83F (on ENST00000418998 / NM_001377303.1; = p.S61F on NM_032107.5) | Missense Mutation (SNP) | VAF 30/558 reads (5%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.188); catalogued as rs1303984584; called by muse, mutect2
- MAFB | c.653C>A p.S218Y | Missense Mutation (SNP) | VAF 7/118 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs983528122; called by muse, mutect2
- MAMDC4 | c.470G>A p.R157Q | Missense Mutation (SNP) | VAF 7/40 reads (18%) | SIFT tolerated (0.23); PolyPhen benign (0.101); catalogued as rs775759482, COSV99915788; called by muse, mutect2, varscan2
- MMP14 | c.718G>A p.E240K | Missense Mutation (SNP) | VAF 9/157 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1566482096, COSV61289130; called by muse, mutect2
- NHLH2 | c.133G>A p.E45K | Missense Mutation (SNP) | VAF 24/380 reads (6%) | SIFT tolerated (0.73); PolyPhen benign (0.003); catalogued as rs1557829857; called by muse, mutect2
- NXT2 | c.55G>A p.E19K (on ENST00000372106 / NM_001242617.2; = p.E74K on NM_018698.5) | Missense Mutation (SNP) | VAF 24/78 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.897); catalogued as COSV54296505, COSV54296730; called by muse, mutect2, varscan2
- OR2M5 | c.227C>G p.S76C | Missense Mutation (SNP) | VAF 19/208 reads (9%) | SIFT deleterious (0); PolyPhen benign (0.065); catalogued as rs760245297, COSV63546511; called by muse, mutect2
- PA2G4 | c.356C>G p.A119G | Missense Mutation (SNP) | VAF 102/189 reads (54%) | SIFT deleterious (0.02); PolyPhen benign (0.056); catalogued as rs1266911478; called by muse, mutect2, varscan2
- PCDHGA12 | c.529C>G p.H177D | Missense Mutation (SNP) | VAF 6/115 reads (5%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.965); catalogued as COSV52769637; called by muse, mutect2
- PDILT | c.182G>A p.R61H | Missense Mutation (SNP) | VAF 53/254 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.86); catalogued as rs772997693, COSV56705175, COSV99043630; called by muse, mutect2, varscan2
- PKN2 | c.1971C>G p.F657L | Missense Mutation (SNP) | VAF 48/222 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.964); catalogued as COSV60132594; called by muse, mutect2, varscan2
- PRR27 | c.571G>C p.E191Q | Missense Mutation (SNP) | VAF 99/308 reads (32%) | SIFT tolerated (0.37); PolyPhen benign (0.048); catalogued as COSV100748753; called by muse, mutect2, varscan2
- PSG4 | c.353G>T p.G118V | Missense Mutation (SNP) | VAF 22/269 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as rs1190116989, COSV54938476; called by muse, mutect2
- RNPEPL1 | c.985G>T p.E329* | Nonsense Mutation (SNP) | VAF 15/139 reads (11%) | catalogued as COSV99549495; called by muse, mutect2, varscan2
- SCRIB | c.1966C>T p.R656W | Missense Mutation (SNP) | VAF 4/13 reads (31%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.91); catalogued as rs779353810, COSV57586409; called by muse, mutect2, varscan2
- SDK2 | c.4894G>A p.V1632I | Missense Mutation (SNP) | VAF 71/107 reads (66%) | SIFT tolerated (0.26); PolyPhen benign (0.022); catalogued as rs781724733; called by muse, mutect2, varscan2
- SDR39U1 | c.76G>A p.E26K | Missense Mutation (SNP) | VAF 44/269 reads (16%) | SIFT tolerated (0.42); PolyPhen benign (0.003); catalogued as COSV52159844; called by muse, mutect2, varscan2
- SLC2A14 | c.1460G>A p.R487Q | Missense Mutation (SNP) | VAF 38/466 reads (8%) | SIFT tolerated (0.18); PolyPhen benign (0.022); catalogued as rs770162236, COSV61586441; called by muse, mutect2
- SLC35B4 | c.330C>G p.I110M | Missense Mutation (SNP) | VAF 23/117 reads (20%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.543); catalogued as rs770604100; called by muse, mutect2, varscan2
- SLC4A10 | c.568G>C p.E190Q | Missense Mutation (SNP) | VAF 5/54 reads (9%) | SIFT tolerated (1); PolyPhen benign (0.29); catalogued as COSV55801869; called by muse, mutect2
- SPC24 | c.83G>A p.R28Q | Missense Mutation (SNP) | VAF 9/117 reads (8%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.982); catalogued as COSV70607061, COSV70607286; called by muse, mutect2
- TMPRSS15 | c.2329G>T p.A777S | Missense Mutation (SNP) | VAF 69/474 reads (15%) | SIFT deleterious (0.05); PolyPhen benign (0.007); catalogued as rs761371509; called by muse, mutect2, varscan2
- TTN | c.31003C>G p.P10335A (on ENST00000591111; = p.P9408A on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 9/128 reads (7%) | PolyPhen probably damaging (0.996); catalogued as COSV60024222; called by muse, mutect2
- AANAT | c.452C>G p.P151R | Missense Mutation (SNP) | VAF 22/66 reads (33%) | SIFT tolerated (0.08); PolyPhen benign (0.251); called by muse, mutect2, varscan2
- ABCC6 | c.857A>T p.E286V | Missense Mutation (SNP) | VAF 36/586 reads (6%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.632); called by muse, mutect2
- ADAM30 | c.1409G>A p.C470Y | Missense Mutation (SNP) | VAF 14/202 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- ADD2 | c.1494G>C p.M498I | Missense Mutation (SNP) | VAF 7/114 reads (6%) | SIFT tolerated (0.19); PolyPhen benign (0.007); called by muse, mutect2
- AMOTL1 | c.769C>T p.H257Y | Missense Mutation (SNP) | VAF 47/97 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); called by muse, mutect2, varscan2
- ARFGEF1 | c.763G>A p.D255N | Missense Mutation (SNP) | VAF 26/345 reads (8%) | SIFT tolerated (0.2); PolyPhen benign (0.039); called by muse, mutect2
- AURKC | c.838G>C p.E280Q (on ENST00000302804 / NM_001015878.2; = p.E246Q on NM_003160.3) | Missense Mutation (SNP) | VAF 95/290 reads (33%) | SIFT tolerated (0.6); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- BBX | c.2644G>A p.E882K (on ENST00000325805 / NM_001142568.3; = p.E852K on NM_020235.7) | Missense Mutation (SNP) | VAF 20/313 reads (6%) | SIFT deleterious (0.01); PolyPhen benign (0.345); called by muse, mutect2
- BEST1 | c.1740-8C>G | Splice Region (SNP) | VAF 23/492 reads (5%) | called by muse, mutect2
- BHMG1 | c.476C>T p.S159F | Missense Mutation (SNP) | VAF 9/105 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); called by muse, mutect2
- BICRA | c.2677G>A p.E893K | Missense Mutation (SNP) | VAF 43/134 reads (32%) | SIFT tolerated (0.39); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- BRD2 | c.2360C>G p.S787C | Missense Mutation (SNP) | VAF 72/328 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.984); called by muse, mutect2, varscan2
- BRD9 | c.1388G>A p.R463K | Missense Mutation (SNP) | VAF 14/246 reads (6%) | SIFT tolerated (0.23); PolyPhen benign (0.433); called by muse, mutect2
- C9orf131 | c.1252G>T p.E418* | Nonsense Mutation (SNP) | VAF 22/406 reads (5%) | called by muse, mutect2
- CD19 | c.1393G>C p.D465H | Missense Mutation (SNP) | VAF 32/656 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- CD22 | c.2422G>T p.E808* | Nonsense Mutation (SNP) | VAF 16/154 reads (10%) | called by muse, mutect2, varscan2
- CELF5 | c.753C>G p.L251= | Splice Region (SNP) | VAF 7/98 reads (7%) | called by muse, mutect2
- CHD6 | c.2053G>C p.D685H | Missense Mutation (SNP) | VAF 32/492 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2
- COBL | c.3235G>A p.E1079K | Missense Mutation (SNP) | VAF 13/329 reads (4%) | SIFT tolerated (0.09); PolyPhen benign (0.214); called by muse, mutect2
- COL2A1 | c.2623C>G p.Q875E | Missense Mutation (SNP) | VAF 18/326 reads (6%) | SIFT tolerated (0.89); PolyPhen benign (0.162); called by muse, mutect2
- COL6A6 | c.4790G>A p.G1597E | Missense Mutation (SNP) | VAF 20/236 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- COL8A2 | c.26C>T p.S9F | Missense Mutation (SNP) | VAF 10/288 reads (3%) | SIFT tolerated, low confidence (0.7); PolyPhen possibly damaging (0.567); called by muse, mutect2
- COPS4 | c.478G>A p.D160N | Missense Mutation (SNP) | VAF 6/99 reads (6%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.609); called by muse, mutect2
- DDX19B | c.1383G>T p.K461N | Missense Mutation (SNP) | VAF 43/247 reads (17%) | SIFT tolerated (0.14); PolyPhen benign (0.047); called by muse, mutect2, varscan2
- DECR1 | c.670C>G p.L224V | Missense Mutation (SNP) | VAF 12/132 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); called by muse, mutect2
- DENND5B | c.1033C>G p.L345V | Missense Mutation (SNP) | VAF 9/168 reads (5%) | SIFT tolerated (0.35); PolyPhen possibly damaging (0.456); called by muse, mutect2
- ERF | c.449C>T p.S150F | Missense Mutation (SNP) | VAF 20/25 reads (80%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.809); called by muse, mutect2, varscan2
- ERICH6 | c.790G>C p.E264Q | Missense Mutation (SNP) | VAF 13/243 reads (5%) | SIFT tolerated (0.14); PolyPhen benign (0.389); called by muse, mutect2
- FAT2 | c.7688G>A p.G2563E | Missense Mutation (SNP) | VAF 12/323 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- FDFT1 | c.291_308del p.L97_S102del | In Frame Del (DEL) | VAF 15/68 reads (22%) | called by mutect2, pindel, varscan2
- GLI2 | c.998C>T p.S333F | Missense Mutation (SNP) | VAF 13/113 reads (12%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.602); called by muse, mutect2, varscan2
- GRIK5 | c.10G>A p.E4K | Missense Mutation (SNP) | VAF 10/166 reads (6%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.015); called by muse, mutect2
- ISL1 | c.1042G>A p.E348K | Missense Mutation (SNP) | VAF 22/326 reads (7%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.849); called by muse, mutect2
- KATNIP | c.1744-2A>C p.X582_splice | Splice Site (SNP) | VAF 24/76 reads (32%) | called by muse, varscan2
- KCNT1 | c.3193G>A p.G1065S (on ENST00000488444; = p.G1091S on NM_020822.3) | Missense Mutation (SNP) | VAF 78/212 reads (37%) | SIFT tolerated (0.78); PolyPhen benign (0); called by muse, varscan2
- KIAA1109 | c.9673G>T p.V3225F | Missense Mutation (SNP) | VAF 14/26 reads (54%) | SIFT deleterious (0); PolyPhen possibly damaging (0.692); called by muse, mutect2, varscan2
- KRT15 | c.448G>A p.E150K | Missense Mutation (SNP) | VAF 23/78 reads (29%) | SIFT tolerated (0.77); PolyPhen benign (0.038); called by muse, mutect2, varscan2
- LRATD1 | c.268C>T p.R90W | Missense Mutation (SNP) | VAF 9/87 reads (10%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.639); called by muse, mutect2
- LRRC74A | c.571_573del p.S191del | In Frame Del (DEL) | VAF 11/120 reads (9%) | called by pindel, varscan2
- MTRNR2L3 | c.52C>G p.L18V | Missense Mutation (SNP) | VAF 4/90 reads (4%) | PolyPhen possibly damaging (0.578); called by muse, mutect2
- MYO1B | c.3080C>G p.S1027* (on ENST00000304164; = p.S969* on NM_012223.5) | Nonsense Mutation (SNP) | VAF 7/120 reads (6%) | called by muse, mutect2
- NADK | c.508G>T p.D170Y | Missense Mutation (SNP) | VAF 16/352 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.795); called by muse, mutect2
- NFRKB | c.13G>C p.D5H (on ENST00000446488 / NM_001143835.2; = p.D18H on NM_006165.3) | Missense Mutation (SNP) | VAF 15/286 reads (5%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.921); called by muse, mutect2
- NR3C1 | c.1153G>A p.G385S | Missense Mutation (SNP) | VAF 42/210 reads (20%) | SIFT tolerated (0.33); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- OR4C13 | c.188A>T p.Y63F | Missense Mutation (SNP) | VAF 31/217 reads (14%) | SIFT tolerated, low confidence (0.78); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- PDE4A | c.1866G>T p.E622D (on ENST00000380702 / NM_001111307.2; = p.E383D on NM_006202.3) | Missense Mutation (SNP) | VAF 19/255 reads (7%) | SIFT tolerated (0.13); PolyPhen benign (0.007); called by muse, mutect2
- PDE4DIP | c.5749C>T p.Q1917* | Nonsense Mutation (SNP) | VAF 8/124 reads (6%) | called by muse, mutect2
- PDE5A | c.720G>C p.L240F | Missense Mutation (SNP) | VAF 15/44 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); called by muse, mutect2, varscan2
- PHLDB1 | c.668C>T p.S223L | Missense Mutation (SNP) | VAF 19/369 reads (5%) | SIFT tolerated (0.07); PolyPhen benign (0.118); called by muse, mutect2
- PKD1L3 | c.2665C>T p.L889F | Missense Mutation (SNP) | VAF 17/142 reads (12%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- PLD1 | c.2011T>C p.Y671H | Missense Mutation (SNP) | VAF 11/223 reads (5%) | SIFT tolerated (0.47); PolyPhen benign (0.001); called by muse, mutect2
- RBM12 | c.897C>G p.I299M | Missense Mutation (SNP) | VAF 18/234 reads (8%) | SIFT tolerated (0.22); PolyPhen benign (0.177); called by muse, mutect2
- RNF40 | c.478G>C p.E160Q | Missense Mutation (SNP) | VAF 16/150 reads (11%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.852); called by muse, varscan2
- RTN3 | c.5_12del p.A2Vfs*71 (on ENST00000377819 / NM_001265589.2; = p.A2Vfs*129 on NM_006054.4) | Frame Shift Del (DEL) | VAF 4/24 reads (17%) | called by mutect2, pindel, varscan2
- SLC8A2 | c.1127C>T p.S376L | Missense Mutation (SNP) | VAF 11/68 reads (16%) | SIFT tolerated (0.06); PolyPhen benign (0.06); called by muse, mutect2, varscan2
- TCEAL2 | c.57C>A p.D19E | Missense Mutation (SNP) | VAF 13/115 reads (11%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2
- TERF2IP | c.938C>T p.S313F | Missense Mutation (SNP) | VAF 16/306 reads (5%) | called by muse, mutect2
- TEX10 | c.482_485del p.L161* | Frame Shift Del (DEL) | VAF 20/105 reads (19%) | called by mutect2, pindel, varscan2
- TICRR | c.1895C>A p.P632H | Missense Mutation (SNP) | VAF 48/97 reads (49%) | SIFT deleterious (0.01); PolyPhen benign (0.173); called by mutect2, varscan2
- TMED10 | c.466G>C p.D156H | Missense Mutation (SNP) | VAF 18/424 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- UGT2B17 | c.233C>T p.P78L | Missense Mutation (SNP) | VAF 6/102 reads (6%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.831); called by muse, mutect2
- USP25 | c.581G>C p.R194T | Missense Mutation (SNP) | VAF 4/48 reads (8%) | SIFT deleterious (0); PolyPhen benign (0.237); called by muse, mutect2
- WDFY4 | c.289G>T p.E97* | Nonsense Mutation (SNP) | VAF 17/243 reads (7%) | called by muse, mutect2
- WDR44 | c.1486G>C p.D496H | Missense Mutation (SNP) | VAF 8/96 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); called by muse, mutect2
- ZBTB37 | c.554G>A p.R185K | Missense Mutation (SNP) | VAF 12/185 reads (6%) | SIFT tolerated (0.81); PolyPhen benign (0.029); called by muse, mutect2
- ZNF236 | c.382G>A p.D128N | Missense Mutation (SNP) | VAF 6/118 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- ZRANB3 | c.668C>T p.A223V | Missense Mutation (SNP) | VAF 52/106 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); called by muse, mutect2, varscan2
- ACKR2 | c.900C>T p.I300= | Silent (SNP) | VAF 28/128 reads (22%) | catalogued as rs200987829, COSV99825710; called by muse, mutect2, varscan2
- ADCY8 | c.150C>T p.F50= | Silent (SNP) | VAF 9/111 reads (8%) | catalogued as COSV53901101; called by muse, mutect2
- AMFR | c.12C>G p.L4= | Silent (SNP) | VAF 6/78 reads (8%) | catalogued as rs1367192546; called by muse, mutect2
- BACH1 | c.1491C>T p.V497= | Silent (SNP) | VAF 10/159 reads (6%) | called by muse, mutect2
- C9orf131 | c.2331G>A p.G777= | Silent (SNP) | VAF 12/214 reads (6%) | catalogued as COSV56614841; called by muse, mutect2
- CCDC168 | c.8211G>A p.K2737= | Silent (SNP) | VAF 8/68 reads (12%) | called by muse, mutect2, varscan2
- DHODH | c.858G>A p.V286= | Silent (SNP) | VAF 30/374 reads (8%) | called by muse, mutect2
- DLG3 | c.690C>G p.L230= | Silent (SNP) | VAF 6/130 reads (5%) | called by muse, mutect2
- EVI5L | c.1938G>C p.V646= | Silent (SNP) | VAF 26/100 reads (26%) | called by muse, mutect2, varscan2
- FOXG1 | c.1266G>A p.P422= | Silent (SNP) | VAF 82/455 reads (18%) | catalogued as COSV57398595; called by muse, mutect2, varscan2
- GALNT2 | c.33C>T p.F11= | Silent (SNP) | VAF 20/106 reads (19%) | called by muse, mutect2, varscan2
- GLRA2 | c.948G>C p.A316= | Silent (SNP) | VAF 8/158 reads (5%) | catalogued as rs964276490, COSV54337656; called by muse, mutect2
- GRHL2 | c.942C>T p.L314= | Silent (SNP) | VAF 32/426 reads (8%) | catalogued as COSV99307099; called by muse, mutect2
- HCN3 | c.351C>T p.F117= | Silent (SNP) | VAF 51/232 reads (22%) | catalogued as rs1231694564; called by muse, mutect2, varscan2
- HIP1 | c.1297C>T p.L433= | Silent (SNP) | VAF 14/211 reads (7%) | catalogued as rs782168334; called by muse, mutect2
- IRF7 | c.591C>G p.L197= (on ENST00000397566; = p.L184= on NM_001572.5) | Silent (SNP) | VAF 12/138 reads (9%) | catalogued as COSV52762348; called by muse, mutect2
- ITGAL | c.663G>A p.L221= | Silent (SNP) | VAF 13/386 reads (3%) | called by muse, mutect2
- KDM4D | c.1326G>A p.Q442= | Silent (SNP) | VAF 8/150 reads (5%) | called by muse, mutect2
- KIF1B | c.1137G>A p.L379= (on ENST00000377086 / NM_001365952.1; = p.L373= on NM_015074.3) | Silent (SNP) | VAF 14/395 reads (4%) | called by muse, mutect2
- NT5C1B | c.1647G>A p.L549= (on ENST00000359846 / NM_001199086.2; = p.L489= on NM_033253.4) | Silent (SNP) | VAF 33/133 reads (25%) | called by muse, mutect2, varscan2
- PASD1 | c.1728C>T p.V576= | Silent (SNP) | VAF 11/298 reads (4%) | called by muse, mutect2
- PGS1 | c.168C>G p.P56= | Silent (SNP) | VAF 21/104 reads (20%) | called by muse, mutect2
- PIGL | c.184C>T p.L62= | Silent (SNP) | VAF 110/162 reads (68%) | called by muse, mutect2, varscan2
- PPAT | c.99C>T p.I33= | Silent (SNP) | VAF 13/98 reads (13%) | called by muse, mutect2, varscan2
- PYCARD | c.372G>A p.A124= | Silent (SNP) | VAF 24/191 reads (13%) | catalogued as rs1291927856, COSV99910984; called by muse, mutect2, varscan2
- RBM20 | c.372C>T p.L124= | Silent (SNP) | VAF 126/231 reads (55%) | called by muse, mutect2, varscan2
- RNH1 | c.1215C>G p.L405= | Silent (SNP) | VAF 38/450 reads (8%) | called by muse, mutect2
- SAMD1 | c.1298G>A p.*433= | Silent (SNP) | VAF 6/52 reads (12%) | catalogued as COSV99513878, COSV99513905; called by mutect2, varscan2
- SAYSD1 | c.336G>A p.L112= | Silent (SNP) | VAF 24/544 reads (4%) | called by muse, mutect2
- SLC45A4 | c.279G>C p.L93= (on ENST00000517878 / NM_001286646.2; = p.L42= on NM_001080431.2) | Silent (SNP) | VAF 9/74 reads (12%) | called by muse, mutect2, varscan2
- TEX14 | c.4493G>A p.*1498= (on ENST00000240361 / NM_001201457.2; = p.*1452= on NM_031272.5) | Silent (SNP) | VAF 10/189 reads (5%) | called by muse, mutect2
- TRAPPC2 | c.153G>A p.E51= | Silent (SNP) | VAF 14/180 reads (8%) | called by muse, mutect2
- ZNF185 | c.1722G>C p.G574= | Silent (SNP) | VAF 9/75 reads (12%) | called by muse, mutect2, varscan2
- ZNF609 | c.2733G>T p.L911= | Silent (SNP) | VAF 22/203 reads (11%) | called by mutect2, varscan2
- ATP6AP2 | c.-96G>A | 5'UTR (SNP) | VAF 26/207 reads (13%) | called by muse, mutect2, varscan2
- C17orf49 | c.*18C>T | 3'UTR (SNP) | VAF 25/320 reads (8%) | catalogued as rs11548333; called by muse, mutect2
- CCDC159 | c.567+68C>T | Intron (SNP) | VAF 4/46 reads (9%) | called by muse, mutect2
- CDH3 | c.45+44G>A | Intron (SNP) | VAF 10/182 reads (5%) | called by muse, mutect2
- CGB7 | c.-845G>C | 5'UTR (SNP) | VAF 5/27 reads (19%) | catalogued as rs1345818784; called by mutect2, varscan2
- EPHX1 | c.364+42G>A | Intron (SNP) | VAF 9/102 reads (9%) | catalogued as rs1030749288; called by muse, mutect2
- FAM205BP | n.339G>A | RNA (SNP) | VAF 18/434 reads (4%) | called by muse, mutect2
- FBRS | chr16:30662457 C>G | 5'Flank (SNP) | VAF 13/262 reads (5%) | called by muse, mutect2
- FLT4 | c.-29C>G | 5'UTR (SNP) | VAF 18/64 reads (28%) | called by muse, mutect2, varscan2
- HNRNPLL | c.-271G>T | 5'UTR (SNP) | VAF 17/165 reads (10%) | catalogued as rs748642253; called by muse, mutect2
- IGFL1 | c.*3G>A | 3'UTR (SNP) | VAF 53/181 reads (29%) | called by muse, mutect2, varscan2
- IL15 | c.110+559C>T | Intron (SNP) | VAF 6/58 reads (10%) | catalogued as rs958871514; called by muse, mutect2, varscan2
- KLK2 | chr19:50873419 C>T | 5'Flank (SNP) | VAF 9/133 reads (7%) | called by muse, mutect2
- KRT5 | c.1219-10C>T | Intron (SNP) | VAF 36/412 reads (9%) | called by muse, mutect2
- LINC00840 | n.388G>A | RNA (SNP) | VAF 17/274 reads (6%) | called by muse, mutect2
- LINC00840 | n.389A>T | RNA (SNP) | VAF 17/267 reads (6%) | called by muse, mutect2
- LINC00967 | n.947C>G | RNA (SNP) | VAF 39/98 reads (40%) | catalogued as rs1243842612; called by muse, mutect2, varscan2
- NACA4P | n.559G>A | RNA (SNP) | VAF 6/134 reads (4%) | catalogued as rs1276382657; called by muse, mutect2
- NAP1L4 | c.-18+1106G>A | Intron (SNP) | VAF 23/177 reads (13%) | catalogued as rs1405322677; called by muse, mutect2, varscan2
- NDUFA11 | c.-76C>G | 5'UTR (SNP) | VAF 15/161 reads (9%) | called by muse, mutect2
- PHACTR4 | c.-86C>T | 5'UTR (SNP) | VAF 32/165 reads (19%) | catalogued as rs774016582; called by muse, mutect2, varscan2
- RAD23B | c.-72C>T | 5'UTR (SNP) | VAF 5/68 reads (7%) | called by muse, mutect2
- RNF170 | c.*2119G>A | 3'UTR (SNP) | VAF 18/400 reads (5%) | called by muse, mutect2
- TAF1D | c.-178G>T | 5'UTR (SNP) | VAF 8/143 reads (6%) | called by muse, mutect2
- TROAP | c.337+172C>A | Intron (SNP) | VAF 11/198 reads (6%) | called by muse, mutect2
- ZFAND2B | c.-36C>G | 5'UTR (SNP) | VAF 7/67 reads (10%) | called by muse, mutect2
